CCDI case PBCBFW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/e4a6fb6c-d45e-47a5-bad4-edb2d7d4d66f

Demographics
Sex at birth: male.

Diagnoses (1)
1. Pleuropulmonary blastoma: ICD-O-3 morphology code: 8973/3; Tissue or organ of origin: Pleura, NOS; Age at diagnosis: 4.0 years (1,453 days).

Biospecimens (3 samples)
- Sample 0DRO3G: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DRO49: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DU3KA: Tissue type: Tumor; Specimen type: Solid Tissue.
